CCDI case PBBZVE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/a5d20184-cdfc-44da-83a4-8005d536d290

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 17.7 years (6,457 days).

Biospecimens (2 samples)
- Sample 0DO7LW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DO7MC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
